Gene-level copy-number profile of specimen HCM-CSHL-0698-C06-85A from HCMI case HCM-CSHL-0698-C06, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Head, face or neck, NOS; AJCC pathologic stage: Stage II.
Specimen HCM-CSHL-0698-C06-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 61586d54-41fd-4f63-a029-eb0ff3222048.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0698-C06-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,247 have no estimate.
https://portal.gdc.cancer.gov/files/eb38dfbd-d10f-4dbc-8f2d-7d02a59f3732

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 348; copy number 2: 3,316; copy number 3: 11,929; copy number 4: 16,827; copy number 5: 15,080; copy number 6: 2,005; copy number 7: 4,989; copy number 8: 583; copy number 9: 1,520; copy number 10: 231; copy number 11: 637; copy number 12: 629; copy number 13: 15; copy number 14: 43; copy number 15: 14; copy number 16: 17; copy number 19: 1; copy number 21: 2; copy number 29: 11; copy number 30: 3; copy number 31: 6; copy number 32: 7; copy number 35: 8; copy number 36: 3; copy number 37: 134; copy number 41: 17; copy number 43: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 3,299 genes in 31 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:179,829,609–180,114,875, 10 genes, copy number 9: LINC02818, TOR1AIP2, AL353708.3, TOR1AIP1, RN7SL230P, AL353708.2, AL353708.1, CEP350, RPSAP16, AL590632.1.
- chr1:180,509,380–180,566,523, 2 genes, copy number 9: OVAAL, Y_RNA.
- chr1:180,906,651–181,182,208, 10 genes, copy number 9: LINC02816, KIAA1614, AL162431.1, KIAA1614-AS1, AL162431.2, AL162431.3, STX6, MR1, IER5, LINC01732.
- chr1:182,899,865–183,928,532, 21 genes, copy number 9: SHCBP1L, HMGN1P4, 5S_rRNA, AL450304.1, KRT18P28, RNU6-41P, LAMC1, LAMC1-AS1, LAMC2, NMNAT2, AL354953.1, RPS3AP8, AL449223.1, SMG7-AS1, SMG7, NCF2, ARPC5, RGL1, APOBEC4, AL157899.1, AL590422.1.
- chr1:184,171,714–184,672,166, 9 genes, copy number 9: Y_RNA, Y_RNA, AL445228.1, RN7SL654P, AL445228.2, C1orf21, AL078645.1, AL078645.2, AL713852.1.
- chr1:184,790,724–185,520,986, 22 genes, copy number 9: NIBAN1, RNU7-13P, LINC01633, RNA5SP72, RNF2, FTH1P25, TRMT1L, SWT1, RPL22P24, RPL5P5, Y_RNA, Y_RNA, AL356273.1, Y_RNA, AL356273.2, AL356273.3, IVNS1ABP, AL078644.1, GS1-279B7.1, RNU7-183P, MCRIP2P2, AL133383.2.
- chr1:185,646,463–186,190,949, 2 genes, copy number 9 (within-gene range 8–9): AL133383.1, HMCN1.
- chr1:186,296,279–186,522,304, 7 genes, copy number 9: PRG4, TPR, RNU6-1240P, ODR4, PDC-AS1, PDC, AL096803.3.
- chr1:186,671,791–188,536,465, 15 genes, copy number 9: PTGS2, PACERR, PLA2G4A, LINC01036, AL391813.1, FDPSP1, AL357559.1, SLC4A1APP2, AL645474.1, AL136372.2, AL136372.1, RN7SKP156, AL596211.1, AL592447.1, AL929288.1.
- chr2:38,814–1,744,852, 36 genes, copy number 9–10: FAM110C, AC079779.1, SH3YL1, ACP1, ALKAL2, AC079779.2, AC079779.3, AC079779.4, LINC01865, AC105393.2, AC105393.1, LINC01874, LINC01875, AC093326.1, TMEM18, TMEM18-DT, AC092159.3, AC092159.2, AC092159.1, AC116609.3, AC116609.2, AC116609.1, LINC01115, LINC01939, AC113607.1, SNTG2-AS1, SNTG2, AC114808.1, AC114808.2, AC108462.1, AC105450.1, TPO, AC141930.1, AC141930.2, AC144450.1, PXDN.
- chr2:2,895,048–23,199,056, 283 genes, copy number 9–10 (broad region; genes not listed).
- chr2:85,068,809–85,069,031, 1 gene, copy number 12: AC078974.1.
- chr2:89,319,625–92,035,000, 62 genes, copy number 10–15 (broad region; genes not listed).
- chr3:93,843,764–198,123,232, 1,753 genes, copy number 9–12 (broad region; genes not listed).
- chr4:98,470,367–98,658,611, 2 genes, copy number 9: TSPAN5, AC108159.1.
- chr7:27,048,169–27,048,628, 1 gene, copy number 9: NHP2P2.
- chr7:55,656,768–55,739,605, 6 genes, copy number 9: AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11.
- chr8:39,314,591–40,127,468, 13 genes, copy number 10–43: ADAM5, ADAM3A, AC123767.1, ADAM18, ADAM2, AP005902.2, AP005902.1, IDO1, AC007991.3, AC007991.2, AC007991.4, AC087518.1, LINC02866.
- chr11:45,371,397–45,388,511, 1 gene, copy number 9 (within-gene range 7–9): LINC02687.
- chr11:45,847,118–45,883,248, 1 gene, copy number 9: CRY2.
- chr11:55,279,447–55,344,231, 7 genes, copy number 9: AP005597.3, AP005597.2, TRIM51HP, AP005597.1, OR4A11P, OR4A12P, OR4A16.
- chr11:55,506,635–55,511,169, 1 gene, copy number 9: OR4C1P.
- chr11:55,773,438–55,820,597, 5 genes, copy number 9: OR5D13, OR5D15P, OR5D14, OR5L1, OR5D18.
- chr11:56,049,785–56,072,049, 2 genes, copy number 9: OR5AQ1P, OR5J1P.
- chr11:56,252,254–56,276,819, 2 genes, copy number 9: OR5T3, OR5T1.
- chr11:68,870,664–70,398,488, 49 genes, copy number 29–41 (within-gene range 6–41): LINC02701, MRPL21, IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1.
- chr11:78,652,829–79,612,300, 7 genes, copy number 11–12 (within-gene range 9–12): TENM4, AP002768.1, AP002957.1, AP001547.1, MIR708, MIR5579, AP001978.1.
- chr13:52,842,889–64,076,044, 84 genes, copy number 9–19 (broad region; genes not listed).
- chr18:45,034–15,330,282, 367 genes, copy number 9 (broad region; genes not listed).
- chr19:37,181,579–39,786,291, 134 genes, copy number 37 (within-gene range 7–37) (broad region; genes not listed).
- chr20:87,250–20,738,731, 384 genes, copy number 9–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 348. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
